Surgical pathology report (de-identified scan), TCGA case TCGA-LG-A9QD, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Hartford Hospital, specimen TCGA-LG-A9QD-01A (Primary Tumor).

[page 1 of 2]
Surgical Pathology Report

██████████
██████████
██████████

DATE OBTAINED:
DATE RECEIVED:
DATE REPORTED:

██████████
██████████
██████████

LOCATION:
SUBMITTING MD:
CC:

DIAGNOSIS

PARTIAL HEPATECTOMY (647 G) LEFT LATERAL (SEGMENT III): HEPATOCELLULAR CARCINOMA.

Tumor type:	Hepatocellular carcinoma
Histologic grade:	Variable including grade I of IV (well differentiated adenoma-like) and grade II-III of IV (moderately differentiated)
Tumor size:	15 cm pedunculated tumor (with gastric compression clinically) 2 cm satellite tumor (approaching but not transected at parenchymal margin)
Tumor multifocality:	Present, as above
Vascular invasion:	Not present
Hepatic capsule:	No transcapsular invasion
Local extension:	Organ-confined
Margins:	-Hepatic parenchymal: negative (~1 mm) -Bile duct(s): N/A -Vascular: N/A
Lymph nodes:	N/A
Other findings:	Steatosis (35-40%) and Mallory hyaline in well differentiated HCC; focal tumor necrosis & hyalinization present; no background cirrhosis; non-specific triaditis; focal peliosis
AJCC stage:	Stage IIIA; pT3a (assuming "cN0" and "cM0" status)

Electronically Signed Out

COMMENT

As per the OP note, this represents a palliative resection to relieve gastric compression. Other lesions were reportedly present via intraoperative ultrasound. Note is made of the prior core biopsy.

Histologically this tumor shows equal components of well differentiated adenoma-like HCC with clonal evolution to a more moderately differentiated HCC.

88329, 88309

Clinical Diagnosis and History:

Hepatocellular cancer

Tissue(s) Submitted:

LEFT LATERAL SEGMENT

ICD-O-3
Carcinoma, hepatocellular NOS 8170/3
Site: Liver C22.0
9/27/14

Gross Description:

The specimen is received fresh for intraoperative consult and subsequently placed in formalin labeled left lateral liver segment and consists of a 21.5 (M to L) x 12 (S to I) x 5 (A to P) liver segment weighing 647 grams. The parenchymal resection margin is 6 x 14

[page 2 of 2]
cm in area. The capsule is dark brown and smooth with no capsular-invasive nodules. There is a 15 x 10 x 7.5 cm variegated heterogenous, circular tan-yellow lesion with focal areas of hemorrhage and necrosis on the cut surface. There is also a satellite nodule measuring 2 x 1.7 x 1.5 cm approaching but not transected at the parenchymal resection margin. The uninvolved liver parenchyma is tan-brown without nodularity. Representative samples are submitted labeled 1A – 1R.

- 1A: satellite nodule to margin
- 1B: main tumor to margin
- 1C: main tumor to capsule
- 1D: main tumor to normal
- 1E-1M: representative tumor
- 1N-1O: representative normal parenchyma
- 1P: normal parenchyma to margin
- 1Q: tumor to normal parenchyma to capsule
- 1R: additional tumor

Intraoperative Consult Diagnosis

Hepatocellular tumor; A representative section of tumor was submitted for .issue banking), upon O.R. receipt.

END OF REPORT

Source: NCI Genomic Data Commons file f8454c88-9093-42c3-93ac-de7afd9ff61c (TCGA-LG-A9QD.D5BAD949-7001-4FAC-A7B4-E9B426A53A76.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).